Gene-level copy-number profile of tumor specimen TCGA-19-0957-01C from TCGA case TCGA-19-0957, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 48.5 years (17,714 days).
Specimen TCGA-19-0957-01C: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.6ef0a6b6-1472-4471-8c3e-0e5596a9158c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-19-0957-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7c060176-8126-4868-84f8-5ce5684cc237

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3,635; copy number 2: 48,869; copy number 3: 4,196; copy number 4: 3,019; copy number 23: 6; copy number 24: 5; copy number 25: 34; copy number 28: 3; copy number 29: 10; copy number 30: 12; copy number 33: 12; copy number 34: 5; copy number 46: 12.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-19-0957-01C-01D-0591-01): tumor purity 0.74, ploidy 2.08, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 99 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:51,843,000–52,551,574, 10 genes, copy number 30 (within-gene range 2–30): DCUN1D4, DUTP7, AC027271.1, AC104784.1, LRRC66, SGCB, LINC02480, SPATA18, AC097522.2, AC097522.1.
- chr4:52,862,317–52,866,835, 1 gene, copy number 30: RASL11B.
- chr4:52,945,649–52,958,087, 1 gene, copy number 30: AC023154.1.
- chr4:54,009,789–54,376,752, 10 genes, copy number 29: CHIC2, AC110792.2, AC110792.4, AC110792.1, MORF4L2P1, GSX2, RPL22P13, PDGFRA, LINC02283, AC098587.1.
- chr4:61,201,258–62,078,335, 1 gene, copy number 33 (within-gene range 1–33): ADGRL3.
- chr4:61,420,246–62,510,771, 11 genes, copy number 33: AC020741.1, AC108161.1, Y_RNA, ADGRL3-AS1, RPS15AP17, AC007511.1, RPL21P47, AC105313.1, AC074087.2, AC074087.1, HMGN1P11.
- chr12:57,610,180–57,984,761, 33 genes, copy number 25: ARHGEF25, AC025165.1, AC025165.6, SLC26A10, B4GALNT1, RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2.
- chr12:58,244,378–58,244,865, 1 gene, copy number 25: RPL21P103.
- chr12:61,708,259–62,279,150, 5 genes, copy number 24 (within-gene range 1–24): TAFA2, RPL21P104, KRT8P19, RPS3P6, AC078789.1.
- chr12:67,351,436–67,442,559, 3 genes, copy number 28: MRPL40P1, NTAN1P3, LINC02420.
- chr12:67,929,235–68,234,686, 5 genes, copy number 34 (within-gene range 1–43): LINC01479, AC005294.1, IFNG-AS1, RPL39P28, HNRNPA1P70.
- chr12:68,686,951–68,971,570, 12 genes, copy number 46 (within-gene range 1–46): NUP107, KRT8P39, SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1.
- chr12:71,439,798–71,667,725, 6 genes, copy number 23 (within-gene range 1–23): LGR5, AC090116.1, AC078860.3, AC078860.2, ZFC3H1, AC078860.1.

Autosomal genes at a single copy (total copy number 1): 3,635. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
